Gene-level copy-number profile of tumor specimen TCGA-19-5959-01A from TCGA case TCGA-19-5959, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 77.9 years (28,449 days).
Specimen TCGA-19-5959-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.f2086e38-fb73-4e87-b599-c723709632e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-19-5959-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b947bfa-ef9d-4d27-bc87-f4010d78ff58

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 3,418; copy number 2: 50,760; copy number 3: 5,545; copy number 4: 22; copy number 39: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-19-5959-01A-11D-1694-01): tumor purity 0.92, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:17,906,563–18,910,950, 5 genes (within-gene range 0–1): ADAMTSL1, AL442638.1, MIR3152, RN7SKP258, RAP1BP1.
- chr9:20,999,509–23,438,700, 61 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,933,699–55,211,628, 3 genes, copy number 39: AC006971.1, EGFR, EGFR-AS1.
- chr7:55,876,738–55,955,239, 4 genes, copy number 39: AC092647.1, AC092647.2, AC092647.5, ZNF713.
- chr7:55,951,877–55,956,500, 1 gene, copy number 39: MRPS17.

Autosomal genes at a single copy (total copy number 1): 3,418. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
